Surgical pathology report (de-identified scan), TCGA case TCGA-BD-A3EP, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BD-A3EP-01A (Primary Tumor).

[page 1 of 2]
PATIENT HISTORY:
CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Hepatocellular carcinoma.
PROCEDURE: Liver resection cholecystectomy.
SPECIFIC CLINICAL QUESTION: Not answered.
OUTSIDE TISSUE DIAGNOSIS: Not answered.
PRIOR MALIGNANCY: Not answered.
CHEMORADIATION THERAPY: Not answered.
ORGAN TRANSPLANT: Not answered.
IMMUNOSUPPRESSION: Not answered.
OTHER DISEASES: Not answered.

FINAL DIAGNOSIS:

PART 1. LYMPH NODE, COMMON BILE DUCT, BIOPSY: Date of
ONE BENIGN LYMPH NODE WITH LIPOGRANULOMATOUS REACTION, NO TUMOR SEEN
(0/1).

PART 2. LYMPH NODE, PANCREATIC, BIOPSY:
ONE BENIGN LYMPH NODE WITH LIPOGRANULOMATOUS REACTION, NO TUMOR SEEN
(0/1).

PART 3. LIVER, RIGHT LOBE, PARTIAL LOBECTOMY:
A. MODERATELY DIFFERENTIATED HEPATOCELLULAR CARCINOMA, SOLITARY.
a. 2.5 CM IN GREATEST DIMENSION.
b. NO ANGIOLYMPHATIC INVASION SEEN.
c. SURGICAL RESECTION MARGINS FREE OF TUMOR
d. PTNM = pT1N0.
B. BACKGROUND LIVER WITH:
a. MILD MIXED MICRO- AND MACROVESICULAR STEATOSIS INVOLVING 10-20% OF
THE HEPATOCYTES (SEE COMMENT).

b. MILDLY ACTIVE STEATOHEPATITIS (NAFLD ACTIVITY SCORE (NAS) = 2/8).
c. MILD PORTAL FIBROSIS AND FOCAL DELICATE CENTRIZONAL SUBSINUSOIDAL
FIBROSIS (FIBROSIS STAGE = 2/4).

PART 4. GALLBLADDER, CHOLECYSTECTOMY:
A. CHRONIC CHOLECYSTITIS WITH CHOLELITHIASIS.
B. MUCOSAL AUTOLYSIS.

C. ONE BENIGN LYMPH NODE WITH LIPOGRANULOMATOUS REACTION, NO TUMOR SEEN
(0/1)

COMMENT:

Part 3: The histopathological changes of the non-neoplastic liver are most consistent with an active steatohepatitis, although other causes of liver injury should be clinically and serologically excluded. Steatohepatitis is a non-specific pattern of injury seen most commonly with morbid obesity, diabetes, insulin resistance, and alcohol abuse. However, it can also be associated with nutritional causes, such as protein-calorie malnutrition, starvation, rapid weight loss, and various intestinal bypass or gastric stapling surgeries. Hepatic steatosis and steatohepatitis can also be the result of medications, including amiodarone, perhexiline maleate, glucocorticoids, synthetic estrogens, calcium channel blockers, tamoxifen, methotrexate, valproic acid, cocaine, and anti-viral agents (Zidovudine, Didanosine, and Fialuridine). Metabolic disorders can also cause steatosis and steatohepatitis: hyperlipidemia, Wilson's disease, adult onset citrullinemia (type II), lipodystrophy, dysbetalipoproteinemia, Weber-Christian-Disease, Wolman's Disease, Cholesterol ester storage disease, and fatty liver of pregnancy. Other causes include inflammatory bowel disease, intestinal bacterial overgrowth, and exposure to environmental toxins, including phosphorous, petrochemicals, toxic mushrooms, and organic solvents. Hepatic blood flow

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY LIVER HEPATOCELLULAR CARCINOMA TUMORS
SPECIMEN TYPE: Other: partial right lobectomy
FOCALITY: Solitary: right lobe

TUMOR SIZE: Greatest dimension: 2.5 cm
Additional dimensions: 2.5 x 2.0 x 2.0 cm

HISTOLOGIC TYPE: Hepatocellular carcinoma
HISTOLOGIC GRADE: G1: Moderately differentiated

MACROSCOPIC VENOUS (LARGE VESSEL) INVASION (V):
Not identified

MICROSCOPIC (SMALL VESSEL) INVASION (L):
Not identified

LIVER-PERINEURAL INVASION: Not identified
PATHOLOGIC STAGING (PTNM): pT1

pM0
Number of regional lymph nodes examined: 3
Number of nodes regional lymph involved: 0
pM0

MARGINS:
Parenchymal Margin uninvolved by invasive carcinoma
Parenchymal Margin: Distance of invasive carcinoma from closest margin:
0.6 mm

Margin: parenchyma resection margin
Other margin: hepatic vein margin
ADDITIONAL PATHOLOGIC FINDINGS: No fibrosis to moderate fibrosis
Hepatitis Type: mild steatohepatitis

Diagnostic Discrepancy		

1cA--0-3
carcinoma, hepatocellular, NOS 8/70/3
Site: liver c.a.o. w/ 11/4/11

[page 2 of 2]
Amended date:
Reason: Typographical error in addendum.
This report is being amended to correct the typographical error in A previously reported as 10q23.31 to 10q23.31.
Or final sign-out date:
This Amended Report super
and should be the only one used for patient management. All reports, both original and amended, are maintained in electronic archives and are available upon request.

ADDENDUM:

Addendum: * AMENDED/CORRECTED *
Molecular Anatomic Pathology Testing:
Block 3D

A. Loss of heterozygosity is IDENTIFIED at chromosome 10q23.31 (54%) and 17p13.1 (44%).
B. Fractional Allelic Loss is 18% (2 loci with loss/11 informative loci)

Note:

LOH of high amplitude is considered when more than 75% of cellular DNA is affected.
Loss of heterozygosity of tumor suppressor gene alleles is known to occur in

liver neoplasias and to correlate with tumor progression. As reported in the literature, benign neoplasms (hepatic adenoma and focal nodular hyperplasia) typically have low frequency of LOH (mean fractional allelic loss -6%) and hepatocellular carcinomas (HCC) frequently have higher prevalence of LOH (mean fractional allelic loss -30%) (1,2). Some studies have shown that HCC with LOH of <10% are associated with indolent biological behavior and FAL of >10% with an aggressive biological behavior (3-5). LOH mutations are reported as high amplitude LOH mutations and FAL 25-35% considered to be indeterminate therefore, the LOH profile should be interpreted in the context of the cytologic and histologic findings and the patient's clinical history.
Sample Preparation and LOH Analysis
Manual microdissection of the tissue sample was performed to include tumor tissue and normal adjacent tissues (if available) or a blood sample. DNA was isolated using standard laboratory procedures. Specimens with the minimum of 50% of tumor cells in a microdissection target are accepted for the analysis. Optical density readings were obtained.
Eighteen microsatellite markers (listed below) that have been previously found to be involved in liver neoplasia and/or co-localize with known tumor suppressor genes were used for analysis. PCR was performed using fluorescently labeled primers and the products of amplification were detected using capillary electrophoresis on a platform. Relative fluorescence was calculated.
A. Normal tissue was examined to determine whether the tissue was then analyzed to detect loss of heterozygosity. Thresholds for significant allelic imbalance were determined using normal (non-neoplastic) NS) / (H/RS) formula and reported when allelic ratio for a particular marker was below 0.5 or above 1.0. When normal tissue was not available, peak height ratios falling outside of 2 SDs beyond the mean for each polymorphic allele pairing were assessed as showing loss of heterozygosity.

Marker	Chromosome	Gene
D18S173	1p36	CHN/RIS
D3S1539	3p26	VHL/CCO1
D3S1516	3p26	VHL/CCO1
D5S1344	5q23	APC
D5S618	5q23	APC
D8S254	8p23	---
D8S261	8p23	---
D9S251	9p23	CDKN2A
D9S1748	9p23	CDKN2A
D10S120	10q23	PTEN
D10S173	10q23	PTEN
D17S974	17p13	TP53
D17S1269	17p13	TP53
D17S1877	17p13	Her2/neu
D18S487	18q21	CCO
D21S1256	21q22	ETS2
D22S268	22q13	NP2

1. Chromosomal analysis of hepatic adenoma and focal nodular hyperplasia by comparative genomic hybridization. *Genes Chromosomes Cancer*. 2002 Oct;15(2):139-43.
2. Molecular mechanisms in hepatocellular carcinoma development. *Best Pract Res Clin Gastroenterol*. 2005 Feb;19(1):25-37.
3. Finkelstein SD, et al. Microdissection-based allelotyping discriminates de novo tumor from intrahepatic spread in hepatocellular carcinoma. *Hepatology*. 2003 Apr;37(4):871-8.
4. Marsh JW, et al. Genotyping of hepatocellular carcinoma in liver

abnormalities can also cause hepatic steatosis and steatohepatitis. Examples include pre-hepatic portal hypertension, porto-systemic shunting, and patent ductus venosus.
A copy of the manuscript describing the grading and staging steatohepatitis is on file in the department of pathology (Kleiner D.E., Brunt E.M., Van Natta M., Behling C., Contos M.J., Cummings O.W., Ferrell L.D., Liu Y.-C., Torbenson M.S., Diaz-Ariza A., Yeh M., McCullough A.J., Caviglia A.J. for the Nonalcoholic Steatohepatitis Clinical Research Network. Design and validation of a histological scoring system for nonalcoholic fatty liver disease. *Hepatology* 41:1313-1321, 2005.1.

Source: NCI Genomic Data Commons file 1738b69b-b408-44ec-8b21-6bea4b2db8a2 (TCGA-BD-A3EP.4560D451-6F7E-4F3F-8AF7-F393DB000ABD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).